Somatic mutation profile of tumor specimen TCGA-DB-A4XE-01A (aliquot TCGA-DB-A4XE-01A-11D-A27K-08) from TCGA case TCGA-DB-A4XE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Temporal lobe; Tumor grade: G3; Age at diagnosis: 27.8 years (10,150 days).
Specimen TCGA-DB-A4XE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d92efdf1-efb2-47ba-86bd-e9559b0f13c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XE-10A (Blood Derived Normal), aliquot TCGA-DB-A4XE-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef653030-2e92-4380-a304-76acb9388fa4

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/74 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-2del p.X33_splice | Splice Site (DEL) | VAF 144/394 reads (37%) | hotspot (GDC flag); catalogued as rs1567557258, COSV52678373, COSV52848662, COSV53375861, COSV53887648; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCB10 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV60620301; called by muse, mutect2
- ARHGAP31 | c.2116T>G p.S706A | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV51790311; called by muse, mutect2, varscan2
- BMERB1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV100252855, COSV55506759; called by muse, mutect2, varscan2
- EMILIN2 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs1351725068, COSV54422033; called by muse, mutect2, varscan2
- FYCO1 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV56114579; called by muse, mutect2
- GDAP1 | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV55185164; called by muse, mutect2, varscan2
- GLI3 | c.2330A>G p.H777R | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV67886393; called by muse, mutect2, varscan2
- HIPK1 | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.438); catalogued as rs776744666, COSV61246694; called by muse, mutect2, varscan2
- LRP6 | c.3485A>T p.K1162I | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV53784702; called by muse, mutect2, varscan2
- MAGEA12 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV63294355; called by muse, mutect2
- MAPK8 | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64408616; called by muse, mutect2, varscan2
- NLGN3 | c.71T>A p.L24H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV62442086; called by muse, mutect2, varscan2
- NRK | c.3438T>A p.N1146K | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54592202, COSV99688633; called by muse, mutect2, varscan2
- PNLIPRP1 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62611216; called by muse, mutect2, varscan2
- RPS2 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51909629; called by muse, mutect2, varscan2
- TTR | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as COSV52701268; called by muse, mutect2
- ZNF707 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV62311114; called by muse, mutect2
- ATRX | c.566_567del p.H189Pfs*9 | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | called by pindel, varscan2
- GABRA6 | c.894A>T p.S298= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as COSV50878449; called by muse, mutect2
- IL27 | c.723C>T p.P241= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV60489348; called by muse, mutect2
- PDLIM7 | c.471G>A p.P157= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs145886743, COSV62883052; called by muse, mutect2, varscan2
- PRAMEF19 | c.516G>A p.Q172= | Silent (SNP) | VAF 13/275 reads (5%) | called by muse, mutect2
- ROBO2 | c.1939C>T p.L647= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV59902287; called by muse, mutect2, varscan2
- SGSM2 | c.2916C>A p.I972= (on ENST00000426855 / NM_001098509.2; = p.I1017= on NM_014853.3) | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV51511392; called by muse, mutect2, varscan2
- SLC7A2 | c.918C>A p.V306= (on ENST00000494857 / NM_001370338.1; = p.V346= on NM_003046.6) | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV50249037; called by muse, mutect2, varscan2
- TUBA3C | c.297G>A p.A99= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as rs142499533; called by muse, mutect2
